Gene-level copy-number profile of tumor specimen TCGA-A6-3810-01B from TCGA case TCGA-A6-3810, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 63.0 years (22,999 days).
Specimen TCGA-A6-3810-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-COAD.ae4bc42b-e969-4f86-95f0-fb38d7525c0b.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-A6-3810-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 360 have no estimate.
https://portal.gdc.cancer.gov/files/053c4c65-aa0f-477c-a4b9-402cc5b8220a

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 19; copy number 1: 3,276; copy number 2: 46,624; copy number 3: 8,552; copy number 4: 1,464; copy number 5: 255; copy number 6: 15; copy number 8: 44; copy number 9: 6; copy number 10: 2; copy number 11: 4; copy number 17: 1; copy number 35: 1.
ABSOLUTE estimates for another vial of this sample (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-A6-3810-01A-01D-A274-01): tumor purity 0.6, ploidy 3.16, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 19 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:72,323,028–72,330,751, 1 gene: AC095056.1.
- chr5:94,979,151–94,980,893, 1 gene: MCTP1-AS1.
- chr7:110,590,082–110,592,204, 1 gene: AC073326.2.
- chr7:110,724,159–110,725,825, 1 gene: AC073326.1.
- chr12:118,246,084–118,246,962, 1 gene: RPS2P5.
- chr15:25,159,221–25,170,804, 3 genes: SNORD115, DMAC1P1, SNORD115-1.
- chr16:6,380,476–6,748,969, 5 genes: AC006112.1, AC007223.1, AC007012.2, AC007012.1, RNU7-99P.
- chr19:9,498,678–9,538,645, 4 genes (within-gene range 0–2): AC008567.2, AC008567.3, AC008567.1, ZNF426.
- chr19:47,994,632–48,025,154, 1 gene (within-gene range 0–2): ELSPBP1.
- chr21:31,038,159–31,038,476, 1 gene: KRTAP19-8.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 327 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:84,344,678–84,349,939, 1 gene, copy number 17: AL359273.2.
- chr3:197,950,190–198,222,513, 11 genes, copy number 6: RPL35A, LMLN, RNU6-621P, AC135893.1, LMLN-AS1, ANKRD18DP, RNU6-821P, FRG2FP, TUBB8P8, AC073135.1, FAM157A.
- chr4:154,754,756–154,781,873, 2 genes, copy number 10 (within-gene range 2–10): AC009567.1, AC009567.2.
- chr6:5,997,999–6,007,605, 1 gene, copy number 6: NRN1.
- chr8:46,028,804–46,028,892, 1 gene, copy number 6: AC118650.1.
- chr10:4,201,141–4,243,912, 1 gene, copy number 6 (within-gene range 2–6): LINC00702.
- chr10:87,994,618–87,994,695, 1 gene, copy number 8: AC063965.1.
- chr13:48,303,744–70,171,738, 250 genes, copy number 5–35 (within-gene range 4–35) (broad region; genes not listed).
- chr14:105,419,820–105,499,575, 6 genes, copy number 5 (within-gene range 2–5): MTA1, AL928654.2, CRIP2, CRIP1, AL928654.3, TEDC1.
- chr15:25,054,210–25,062,427, 4 genes, copy number 11: SNORD116-2, SNORD116-3, SNORD116-4, SNORD116-5.
- chr15:25,172,635–25,250,940, 43 genes, copy number 8: SNORD115-2, SNORD115-3, SNORD115-4, SNORD115-5, SNORD115-6, SNORD115-7, SNORD115-8, SNORD115-9, SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25, SNORD115-26, SNORD115-27, SNORD115-28, SNORD115-29, SNORD115-30, SNORD115-31, SNORD115-32, SNORD115-33, SNORD115-34, SNORD115-35, SNORD115-36, SNORD115-37, SNORD115-38, SNORD115-39, SNORD115-40, SNORD115-41, SNORD115-42, SNORD115-43, SNORD115-44.
- chr16:3,088,890–3,149,963, 6 genes, copy number 9 (within-gene range 2–9): ZSCAN10, ZNF213-AS1, AC108134.4, ZNF205, ZNF213, CASP16P.

Autosomal genes at a single copy (total copy number 1): 362. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
